Somatic mutation profile of tumor specimen MMRF_1049_3_BM_CD138pos (aliquot MMRF_1049_3_BM_CD138pos_T1_KHS5U_L12889) from MMRF case MMRF_1049, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.0 years (24,843 days).
Specimen MMRF_1049_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a013a27-5000-47a5-a10d-6c7a5a72ebff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1049_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1049_1_PB_Whole_C2_KHS5U_K14065; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3df48f38-a44a-4309-9f2d-c43f2a5e5269

The open-access MAF lists 124 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 22, Intron 20, Silent 14, 5'UTR 10, 5'Flank 5, RNA 5, Nonsense Mutation 4, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1355815263, COSV51402328; called by muse, mutect2, varscan2
- BMP4 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs1258588645; called by muse, mutect2, varscan2
- CDK2AP1 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs762855598; called by muse, mutect2
- EGR1 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs199695186; called by muse, mutect2, varscan2
- ELAVL4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs200396874, COSV100836643; called by muse, mutect2, varscan2
- GABRA5 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 70/233 reads (30%) | catalogued as COSV59475659; called by muse, mutect2, varscan2
- GJD2 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51747204; called by muse, mutect2, varscan2
- HKDC1 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100664333; called by muse, mutect2, varscan2
- IGHV4-34 | c.326G>C p.S109T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs765275600; called by mutect2, varscan2
- IGKV4-1 | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs368410084; called by muse, mutect2, varscan2
- IGSF9 | c.2296G>A p.A766T (on ENST00000368094 / NM_001135050.2; = p.A750T on NM_020789.4) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.177); catalogued as rs906876689; called by muse, mutect2, varscan2
- IRS4 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 33/145 reads (23%) | catalogued as COSV100929429; called by muse, mutect2, varscan2
- KCTD17 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.039); catalogued as rs1261369510; called by muse, mutect2, varscan2
- KLRF1 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV54380568; called by muse, varscan2
- MISP | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV53119921; called by muse, mutect2, varscan2
- OR4D5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs141977995, COSV100189634; called by muse, mutect2, varscan2
- PCDHGA3 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53951173; called by muse, mutect2
- PP2D1 | c.1486C>A p.L496I | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as rs1247260402; called by muse, mutect2
- SALL3 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs750854739; called by muse, mutect2
- SYNGAP1 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs574603811; called by muse, mutect2, varscan2
- TSPOAP1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs765140985, COSV52109382; called by muse, mutect2, varscan2
- ZFP57 | c.1321C>A p.L441I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs564988086; called by muse, mutect2, varscan2
- ZNF223 | c.233C>A p.S78* | Nonsense Mutation (SNP) | VAF 30/363 reads (8%) | catalogued as COSV71571828; called by muse, mutect2
- AFTPH | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 52/438 reads (12%) | called by muse, mutect2, varscan2
- AP4B1 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CCNC | c.448T>G p.L150V | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- CNGA2 | c.1514A>G p.D505G | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWH43 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GTSE1 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 8/241 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2
- HDHD2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HSPD1 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGBP1P2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHV2-70D | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IRAG1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); called by muse, varscan2
- KAT8 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2
- MNT | c.223G>C p.A75P | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PCDH15 | c.4289C>A p.A1430E | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, varscan2
- PRMT8 | c.557G>C p.W186S | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPN22 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- RAB3A | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.212); called by muse, mutect2
- RASGRF2 | c.2165G>A p.C722Y | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- RPL10 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SRCAP | c.2134T>A p.W712R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUPT5H | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2
- TENT5C | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TGM1 | c.509-2A>T p.X170_splice | Splice Site (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- TMEM26 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCA1 | c.6765A>G p.K2255= | Silent (SNP) | VAF 45/346 reads (13%) | called by muse, mutect2, varscan2
- ABCA7 | c.4875G>C p.L1625= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs754027385; called by muse, mutect2, varscan2
- ADAMTS5 | c.984G>A p.L328= | Silent (SNP) | VAF 26/322 reads (8%) | catalogued as rs760808495; called by muse, mutect2
- AKR7L | c.114C>T p.R38= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs1407149194; called by muse, mutect2
- BTBD1 | c.966A>G p.R322= | Silent (SNP) | VAF 33/307 reads (11%) | called by muse, mutect2
- FOXD3 | c.1179C>T p.G393= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs929422083; called by muse, mutect2
- IGHV2-70D | c.358C>G p.*120= | Silent (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- LOXHD1 | c.57C>T p.Y19= | Silent (SNP) | VAF 25/149 reads (17%) | called by muse, mutect2, varscan2
- LTB4R2 | c.283C>T p.L95= (on ENST00000528054; = p.L64= on NM_019839.5) | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- METTL11B | c.375C>T p.S125= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as rs1456074952, COSV63030163; called by muse, mutect2
- MSH3 | c.984G>T p.R328= | Silent (SNP) | VAF 26/611 reads (4%) | called by muse, mutect2
- PIWIL4 | c.2247C>T p.N749= | Silent (SNP) | VAF 28/318 reads (9%) | catalogued as rs756931190; called by muse, mutect2
- TNS3 | c.2787C>A p.T929= | Silent (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.408C>T p.R136= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- AC020765.6 | c.-42G>A | 5'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- ADH5P5 | chr5:23980142 T>C | 5'Flank (SNP) | VAF 9/86 reads (10%) | called by muse, varscan2
- ARRB1 | c.21-16545C>T | Intron (SNP) | VAF 19/409 reads (5%) | called by muse, mutect2
- B3GALT5-AS1 | n.950G>T | RNA (SNP) | VAF 66/720 reads (9%) | called by muse, mutect2
- BIN1 | chr2:127107270 G>A | 5'Flank (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CCN2 | c.*785T>C | 3'UTR (SNP) | VAF 12/123 reads (10%) | catalogued as rs867008423; called by muse, mutect2
- CDH6 | c.*637A>G | 3'UTR (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- CHUK | c.1975-48C>T | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- CYP3A7 | c.670+133A>G | Intron (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- DEFB134 | chr8:11993557 A>T | 3'Flank (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- DLX6 | c.-246C>G | 5'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2
- FAM171A1 | c.*814G>A | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- FAM217B | c.*1232T>A | 3'UTR (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- FASTKD2 | c.2013+14G>A | Intron (SNP) | VAF 17/162 reads (10%) | catalogued as COSV52700286; called by muse, mutect2, varscan2
- FASTKD2 | c.2013+15C>T | Intron (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- FLCN | c.-24-703_-24-693del | Intron (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- FOXK2 | c.*322G>T | 3'UTR (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+4543C>T | Intron (SNP) | VAF 4/91 reads (4%) | called by muse, mutect2
- FUT7 | chr9:137035862 G>A | 5'Flank (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2, varscan2
- GBX2 | c.-401C>T | 5'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- GOLGA7B | c.*1762T>C | 3'UTR (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- GRIN1 | c.2589+66C>T | Intron (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- IBA57 | c.*493G>A | 3'UTR (SNP) | VAF 24/177 reads (14%) | catalogued as rs941484757; called by muse, mutect2, varscan2
- INTS11 | c.429+196C>T | Intron (SNP) | VAF 15/154 reads (10%) | catalogued as rs755105272; called by muse, mutect2, varscan2
- INTS4P2 | n.1230G>C | RNA (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- ITGA9 | c.2154+54C>A | Intron (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- KIF1A | c.*3162C>A | 3'UTR (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- KIFC3 | c.172+79C>T | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- KLF12 | c.*1496G>A | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- KLRF1 | c.-50T>C | 5'UTR (SNP) | VAF 16/134 reads (12%) | called by muse, varscan2
- KMT5B | c.*1329A>T | 3'UTR (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- KRIT1 | c.486-78_486-77del | Intron (DEL) | VAF 36/163 reads (22%) | called by pindel, varscan2
- LINC02692 | n.828G>T | RNA (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- LTBP1 | c.-179T>G | 5'UTR (SNP) | VAF 37/173 reads (21%) | called by muse, mutect2, varscan2
- LYSMD2 | c.*131C>T | 3'UTR (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- MAGI2 | c.-3G>A | 5'UTR (SNP) | VAF 45/198 reads (23%) | catalogued as rs759941427; called by muse, mutect2, varscan2
- MRGPRX10P | n.245C>T | RNA (SNP) | VAF 14/100 reads (14%) | catalogued as rs1007764171; called by muse, varscan2
- MYRIP | c.-21C>T | 5'UTR (SNP) | VAF 40/320 reads (13%) | called by muse, mutect2, varscan2
- NNAT | chr20:37521224 T>A | 5'Flank (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- NUDT4 | c.*8387T>A | 3'UTR (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- NUP160 | c.*922T>G | 3'UTR (SNP) | VAF 17/88 reads (19%) | called by muse, varscan2
- OCM2 | c.-60T>A | 5'UTR (SNP) | VAF 50/449 reads (11%) | called by muse, mutect2, varscan2
- OR5M4P | n.433T>A | RNA (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- PDGFRB | c.*676C>T | 3'UTR (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- PDLIM3 | c.94-67C>T | Intron (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- PTGER2 | c.*389C>A | 3'UTR (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- RASA3 | c.*352A>G | 3'UTR (SNP) | VAF 10/173 reads (6%) | called by muse, mutect2
- RINL | c.1342+83G>C | Intron (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2
- RND1 | c.*586T>G | 3'UTR (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
- RRP15 | c.*5095C>T | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, varscan2
- SEC16B | c.999-84T>C | Intron (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- SH2B3 | c.*635C>T | 3'UTR (SNP) | VAF 26/190 reads (14%) | called by muse, mutect2, varscan2
- SLC38A10 | c.-243G>A | 5'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- SLIT1 | c.1086-814C>A | Intron (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- SNX13 | c.441-6613_441-6612del | Intron (DEL) | VAF 13/132 reads (10%) | catalogued as rs1376814459; called by mutect2, pindel, varscan2
- SP8 | c.-233A>G | 5'UTR (SNP) | VAF 51/419 reads (12%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.*507A>G | 3'UTR (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- TMEM170A | c.*4274A>G | 3'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- TRAV22 | chr14:22066251 G>A | 5'Flank (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- TSPEAR | c.1566+2127G>A | Intron (SNP) | VAF 20/262 reads (8%) | catalogued as rs906476505; called by muse, mutect2
- TTLL5 | c.740+1680G>A | Intron (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- WNT2B | c.*497C>T | 3'UTR (SNP) | VAF 23/122 reads (19%) | catalogued as rs918441591; called by muse, mutect2, varscan2
- ZIC4 | c.*-147G>T | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2
